Somatic mutation profile of tumor specimen C3L-02129-01 (aliquot CPT0130170012) from CPTAC case C3L-02129, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.9 years (20,422 days).
Specimen C3L-02129-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a136a6b5-46fa-40cd-bd62-fd546d62d77f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02129-31 (Blood Derived Normal), aliquot CPT0130250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f120370-2797-4f65-b8ae-e19697570fef

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 9, Intron 5, Splice Region 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 23/359 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2
- KEAP1 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 39/331 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV50266847; called by muse, mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 19/224 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2
- STK11 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012193, CM067471, COSV58820785; called by muse, mutect2, varscan2
- DEFB112 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as rs532132675, COSV59182558, COSV59182810; called by muse, mutect2, varscan2
- FAM189A1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs896357754, COSV99721228; called by muse, mutect2
- FLT4 | c.3070G>A p.G1024R | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM090220, COSV56111579, COSV99987715; called by muse, mutect2
- KIAA0232 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 40/540 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330326733; called by muse, mutect2
- MEFV | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 64/904 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1294852343, COSV54821685; called by muse, mutect2
- NPAS2 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs771178920; called by muse, mutect2, varscan2
- PTK2 | c.2282A>G p.Y761C | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs1169957667; called by muse, mutect2
- RNF133 | c.499A>T p.I167F | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57390137; called by muse, mutect2
- RNH1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100596695; called by muse, mutect2
- RSAD1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs772178629; called by muse, mutect2
- SLC22A12 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 16/471 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs1365140663, COSV60572076; called by muse, mutect2
- SLC38A8 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 50/566 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1444909552; called by muse, mutect2
- WFIKKN2 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 45/496 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60958298, COSV60959931; called by muse, mutect2
- ACTG1 | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 102/882 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AK9 | c.4425A>T p.E1475D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.182); called by muse, mutect2
- ATP5MD | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2
- CACNA1E | c.5530C>A p.P1844T | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCDC74B | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, varscan2
- CDT1 | c.1389C>A p.S463R | Missense Mutation (SNP) | VAF 40/599 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2
- CNOT2 | c.640A>T p.N214Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.185); called by muse, mutect2
- CPXCR1 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CSMD3 | c.3205G>A p.G1069R (on ENST00000297405 / NM_001363185.1; = p.G965R on NM_052900.3) | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM171A1 | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- GJA5 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GMPPA | c.1164C>T p.G388= | Splice Region (SNP) | VAF 24/156 reads (15%) | called by mutect2, varscan2
- KCND1 | c.517_549del p.W173_T183del | In Frame Del (DEL) | VAF 32/304 reads (11%) | called by mutect2, pindel
- KLHL31 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRK2 | c.6547_6551del p.D2183Kfs*3 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- MAGEB6 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.085); called by muse, varscan2
- MME | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- MPDZ | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2
- NPC1 | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.195); called by muse, mutect2
- OPN1LW | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P4HA3 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- PAPPA2 | c.4993T>C p.Y1665H | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PPP1R3A | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- RPRD1B | c.641T>G p.L214W | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS15A | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2
- SNX25 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SREK1 | c.1476dup p.N493Efs*6 | Frame Shift Ins (INS) | VAF 10/110 reads (9%) | called by mutect2, pindel
- UGT3A1 | c.1296G>A p.R432= | Splice Region (SNP) | VAF 16/152 reads (11%) | called by muse, varscan2
- XPOT | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- ZNF438 | c.1831A>T p.N611Y | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- ANKRD54 | c.78G>T p.A26= | Silent (SNP) | VAF 41/586 reads (7%) | called by muse, mutect2
- DLC1 | c.2862G>T p.V954= (on ENST00000276297 / NM_001348081.2; = p.V517= on NM_006094.5) | Silent (SNP) | VAF 27/384 reads (7%) | catalogued as COSV99364397; called by muse, mutect2
- FSTL5 | c.1725C>T p.T575= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs753867484, COSV60184299; called by muse, varscan2
- GFRA4 | c.202C>T p.L68= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as rs974585411; called by muse, mutect2, varscan2
- HTRA4 | c.1080G>A p.Q360= | Silent (SNP) | VAF 9/258 reads (3%) | called by muse, mutect2
- MAST2 | c.1149C>T p.F383= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- TRAV24 | c.318C>T p.D106= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TRIO | c.6273A>G p.L2091= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as rs1458865400; called by muse, mutect2
- TUT1 | c.1794C>T p.S598= | Silent (SNP) | VAF 47/393 reads (12%) | called by muse, mutect2, varscan2
- ANXA2 | c.528+85A>G | Intron (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- CFAP61 | c.2159+16G>A | Intron (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- GCSH | c.*556G>C | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- LRP5L | n.183T>C | RNA (SNP) | VAF 51/474 reads (11%) | called by muse, mutect2, varscan2
- PRR16 | c.159+16531C>T | Intron (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- PSMB7 | c.511+8498T>C | Intron (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- RPL14 | c.3+199A>T | Intron (SNP) | VAF 16/341 reads (5%) | called by muse, mutect2
